Somatic mutation profile of tumor specimen MP2PRT-PATGCF-TMP1-A (aliquot MP2PRT-PATGCF-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATGCF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,235 days).
Specimen MP2PRT-PATGCF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce6aefa4-6ea0-4517-b63e-554ba37254b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGCF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGCF-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5da8e6f-566d-45fe-bc01-ecfc173a38f8

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4496T>G p.L1499R | Missense Mutation (SNP) | VAF 142/445 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52115693, COSV52125172, COSV52125754; called by muse, mutect2, varscan2
- CSF1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 157/420 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.168); catalogued as rs200057930; called by muse, mutect2, varscan2
- LRRC45 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs754731387; called by muse, mutect2
- BRINP1 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 143/542 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PAPPA | c.3126C>T p.I1042= | Silent (SNP) | VAF 101/379 reads (27%) | catalogued as rs536225461, COSV60285555; called by muse, mutect2, varscan2
- RHOU | c.189G>T p.T63= | Silent (SNP) | VAF 241/626 reads (38%) | called by muse, mutect2, varscan2
- RPN1 | c.63G>T p.P21= | Silent (SNP) | VAF 194/519 reads (37%) | catalogued as rs987233179; called by muse, mutect2, varscan2
